Surgical pathology report (de-identified scan), TCGA case TCGA-23-2643, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2643-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:**SYNOPSIS REPORT:****APPLIES TO:**

A : OMENTUM FS
B : RIGHT OVARY
C : LEFT ADNEXA
D : UTERUS & CERVIX
E : PERITONEUM RT SIDE WALL
F : PERITONEUM LEFT SIDE WALL
G : BLADDER PERITONEUM
H : CECAL NODULE
I : HEPATIC FLEXURE NODULE
J : ILEOCECAL NODULE
K : OMENTAL NODULE
L : INFUNDIBULAR PELVIC

MACROSCOPIC**SPECIMEN TYPE:**

LEFT AND RIGHT OVARIES
UTERUS
OMENTUM
PERITONEUM

OTHER ORGANS PRESENT:

PERICOLIC AND PERI-ILEOCOLIC TISSUES;
INFUNDIBULAR PELVIC LIGAMENT

PROCEDURE:

RIGHT SALPINGO-OOPHORECTOMY
LEFT SALPINGO-OOPHORECTOMY
REMOVAL OF TUMOR IN FRAGMENTS
HYSTERECTOMY
OMENTECTOMY
PERITONEAL BIOPSIES

SPECIMEN INTEGRITY:

INTACT

SPECIMEN INTEGRITY, LEFT OVARY:

INTACT

MICROSCOPIC**HISTOLOGIC TYPE:**

DUS ADENOCARCINOMA

PATIENT NOTIFIED OF RESULTS
DR: NURSE: DATE:

[page 2 of 8]
[REDACTED]

[REDACTED]

HISTOLOGIC GRADE: G3: POORLY DIFFERENTIATED
PRIMARY TUMOR SITE: RIGHT OVARY
TUMOR SIZE: RIGHT OVARIAN TUMOR, GREATEST DIMENSION:
13CM
OVARIAN SURFACE INVOLVEMENT: PRESENT
SUMMARY OF ORGANS/TISSUES MICROSCOPICALLY
INVOLVED BY TUMOR: BOTH OVARIES
FALLOPIAN TUBE(S)
OMENTUM
UTERUS
PERITONEUM
PERICOLIC AND PERILEGOLIC TISSUES AND

[REDACTED]

PRIMARY TUMOR (PT): PTX: CANNOT BE ASSESSED
REGIONAL LYMPH NODES (PN): PNx: CANNOT BE ASSESSED
NUMBER OF LYMPH NODES IDENTIFIED: 0
NUMBER OF LYMPH NODES INVOLVED: 0

A. OMENTUM, PARTIAL OMENECTOMY:

- Metastatic serous carcinoma (see comment)

B. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- Primary ovarian adenocarcinoma, with predominantly serous features, high grade (see comment)
- Tumor subtotally replaces ovary and also focally involves the ovarian serosal surface
- Tumor also involves the fimbriated end of the fallopian tube (mucosa and submucosal stroma)
- Paratubal and paraovarian ligamentous adnexal soft tissues and regional lymphatics are also involved by tumor
- Ovary also shows senescent changes, cystic epithelial inclusions, and serosal adhesions
- Fallopian tube also shows focal transitional epithelial metaplasia at fimbriated end and acute and chronic inflammation
- Paratubal cystic Walthard rest

C. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- Ovary showing extensive involvement by serous carcinoma
- Tumor also involves the serosal surface of the ovary
- Fallopian tube with foci of intraepithelial serous carcinoma (? serous carcinoma in-situ) and focal metastatic carcinoma involving serosal surface
- Carcinoma also involves the paraovarian and paratubal ligamentous tissues and regional lymphatics
- Ovary also shows atrophic changes, serosal adhesions, and multiple cystic epithelial inclusions
- Fallopian tube also shows chronic and acute inflammation

[page 3 of 8]
-
- Paratubal cyst lined by benign serous epithelium (hydatid of Morgagni)
- Paratubal cystic and solid Walthard rests

D. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Metastatic serous carcinoma involving parametrial soft tissues, uterine serosa and subserosa
- No evidence of metastatic carcinoma involving cervix, including surgical margin of cervix
- Subserosal uterine leiomyoma
- Two benign endometrial polyps, one pure endometrial type and other, based in anterior uterine corpus but showing features of mostly cervical-type polyp with surface lining and lining of cystically dilated glands within polyp by mucin-containing columnar cells
- Inactive (atrophic to weakly proliferative) endometrium
- Cervix with acute and chronic inflammation, cystic endocervical tunnel clusters, nabothian cysts, squamous metaplasia, reserve cell hyperplasia, acute and chronic inflammation, reactive epithelial changes, benign endocervical polyp(s), and focal parakeratosis of ectocervical squamous epithelium
- Vaginal cuff mucosa with chronic inflammation

E. SOFT TISSUE, PERITONEUM, RIGHT PELVIC SIDE WALL, EXCISION:

- Metastatic serous carcinoma (see comment)

F. SOFT TISSUE, PERITONEUM, LEFT SIDE WALL, EXCISION:

- Metastatic serous carcinoma (see comment)

G. SOFT TISSUE, BLADDER PERITONEUM, EXCISION:

- Metastatic serous carcinoma (see comment)

H. [SOFT TISSUE], SPECIMEN DESIGNATED "CECAL NODULE", EXCISION:

- Metastatic serous carcinoma (see comment)
- No large intestinal tissue identified

I. [SOFT TISSUE, PERICOLIC/MESENTERIC FAT], SPECIMEN DESIGNATED "HEPATIC FLEXURE NODULE", EXCISION:

- Metastatic serous carcinoma (see comment)
- No large intestinal tissue identified

J. SPECIMEN DESIGNATED "ILEOCECAL NODULE", EXCISION:

- Metastatic serous carcinoma (see comment)
- No small or large intestinal tissue identified

K. OMENTUM, "NODULE", EXCISION:

- Metastatic serous carcinoma (see comment)
- Chronic inflammation and reactive follicular lymphoid aggregates

L. SOFT TISSUE, INFUNDIBULAR PELVIC [LIGAMENT], LATERALITY NOT SPECIFIED, EXCISION:

- Metastatic serous carcinoma (see comment)

COMMENT: Tumor in all involved sites exhibits predominantly features of high-grade serous carcinoma. (Tumor cells showing cytoplasmic clearing are also present in a few sites and the tumor has an "undifferentiated" appearance in a few areas.) Tumor in the

[page 4 of 8]
[REDACTED]

right ovary appears to be primary at that site. The left ovary was not enlarged. It is uncertain whether tumor involving the left ovary represents a synchronous primary neoplasm or a metastasis. In light of the finding of serous intraepithelial carcinoma in the left fallopian tube, the possibility of a second primary tubal neoplasm is considered to be likely. [If this does represent a second primary neoplasm, the tumor stage for the tubal neoplasm would be assigned as follows: pTis, NX.] Lymphovascular invasion by carcinoma is present in most of the involved sites. Secondary acute and chronic inflammatory changes, fibrosing stromal reaction to tumor, and adhesions are present in most of the involved sites. The preliminary pathologic findings were conveyed [REDACTED]

HISTORY:

Ovarian cancer

MICROSCOPIC FINDINGS:

See diagnosis.

SPECIAL STUDIES:

Additional H&E-stained short step sections (B7 x2, C3 x2, D4 x2, D5 x2, D9 x2)

GROSS:

A. OMENTUM

Labeled with the patient's name, labeled "omentum", and received fresh in the Operating Room for frozen section is a partial omentectomy specimen received in two pieces measuring about 23 x 10.5 x 2.0 cm and 9.0 x 7.0 x 2.0 cm.

Both of the tissue fragments are subtotally replaced by nodular aggregates of firm tan-white tumor. The individual tumor nodules range from about 0.2 to 2.5 cm in maximum dimension.

Representative sections are submitted.

Slide key:

A1. Remnant of frozen section A - 1

A2. Smaller and larger portions of omentum, each with tumor - 2

B. RIGHT OVARY

Labeled with the patient's name, labeled "right ovary", and received fresh in the Operating Room and subsequently fixed in formalin is a salpingo-oophorectomy specimen. The ovary is about 13.0 x 12.0 x 10.0 cm. The adjacent fallopian tube has fimbriated at one end, is about 7.0 cm long and ranges from 0.5 to 1.0 cm in diameter.

The ovary is nearly totally replaced by a cystic and solid tan-white neoplasm. Maximum tumor dimension is close to 13.0 cm. The cystic component of the neoplasm accounts for about 75-80% of the total volume and is multiloculated. The cystic loculations range from about 0.5 to 10.0 cm diameter. Some of the cystic loculations contain blood-tinged yellow amber fluid. Most of the cystic loculations are lined by smooth tan tissue and one is partially lined by soft friable tan tumor over an area measuring about 1.5 cm in diameter. The solid component of the tumor which accounts for about 15-25% of the total volume is white-yellow and firm. There are also multiple (about 10 or 12) nodular and plaque-like tumor excrescences on the serosal surface of the ovary involving an area measuring up to about 5.0 cm in diameter. The ovarian capsule is not ruptured. There are similar appearing nodular and plaque-like aggregates of tumor involving the paraovarian and paratubal ligamentous soft tissues. The fimbriated end of the fallopian tube also shows about 1.0 cm diameter deposit of semi-soft to firm tan-white tumor,

[page 5 of 8]
[REDACTED]

Small representative portions of tumor from the left ovary was released to [REDACTED] for research purposes.

Representative sections are submitted.

Slide key:

- B1. Ovary with tumor - 1
- B2. Paraovarian ligamentous tissue with tumor - 2
- B3. Ovary with tumor - 1
- B4. Ovary with tumor - multiple
- B5. Ovary with tumor - 2
- B6. Ovary with tumor - 2
- B7. Fallopian tube and paratubal tissues with tumor - 4

C. LEFT ADNEXA

Labeled with the patient's name, labeled "left adnexa", and received fresh in the Operating Room and subsequently fixed in formalin, is a 16 gram salpingo-oophorectomy specimen. The ovary is about 2.4 x 1.5 x 1.4 cm. The adjacent fimbriated fallopian tube is 4.0 cm long and up to 0.6 cm in diameter.

The ovary is atrophic and partially replaced by nodular aggregates of firm tan-white tumor. Papillated softer friable tan tumor also involves the serosal surface of the ovary. The tumor deposits in the ovary range from about 0.1 to 1.5 cm in diameter. The adjacent fallopian tube appears grossly free of tumor; however, there are small nodular and plaque-like deposits of metastatic tumor in the paratubal ligamentous tissues. The latter tumor deposits measure up to about 0.5 cm in diameter.

A small representative portion of tumor from the ovary was released to [REDACTED] for research purposes.

Representative sections are submitted.

Slide key:

- C1. Ovary with tumor - 3
- C2. Ovary with tumor - 4
- C3. Fallopian tube and paratubal tissues, latter with tumor - multiple
- C4. Ligamentous soft tissues with tumor - multiple

D. UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus and cervix", and received in formalin is a 77 gram intact total hysterectomy specimen. The uterus is about 7.0 x 6.0 x 4.0 cm in greatest overall dimensions. The cervical portion of the uterus alone is about 3.0 cm in length and up to 3.0 cm in diameter. The endometrial cavity is about 3.0 cm long and up to 2.2 cm in width. The flat endometrial mucosa has a maximum thickness of about 0.1 cm. The muscular uterine wall has a maximum thickness of about 1.5 cm.

There are multiple firm tan nodular and plaque-like aggregates of tumor ranging from about 0.1 to 1.0 cm in diameter involving the serosal surface of the uterus, and focally extending into the subserosal possibly subserosal myometrium, and also involving the parametrial tissues. The cervix and a small attached portion of vaginal cuff appear grossly free of tumor.

There is a 2.5 cm diameter subserosal uterine leiomyoma that is composed of firm solid tan-white tissue without grossly evident areas of hemorrhage or necrosis. Two endometrial polyps are also present in the anterior uterine corpus. The polyps are about 0.6 x 0.4 x 0.3 cm and 1.5 x 0.7 x 0.4 cm. Each of the polyps is composed of semisoft tan solid tissue with intervening minute to tiny cystic spaces. The cervix

[page 6 of 8]
[REDACTED]

is remarkable for multiple mucus-filled cysts ranging from about 0.1 to 0.3 cm in maximum dimension. The vaginal cuff is grossly unremarkable.

Representative sections are submitted.

Slide key:

- D1. Anterior cervix, 12:00 to 3:00 - 1
- D2. Anterior cervix, 9:00 to 12:00 - 1
- D3. Posterior cervix, 3:00 to 6:00 - 1
- D4. Posterior cervix, 6:00 to 9:00 - 1
- D5. Anterior uterine corpus with smaller endometrial polyp - 1
- D6. Anterior uterine corpus with larger endometrial polyp - 1
- D7. Uterus with subserosal leiomyoma and serosal involvement by tumor - 1
- D8. Posterior uterine corpus - 1
- D9. Posterior uterine corpus - 1
- D10, D11. Serosal and parametrial tissues with tumor - 2 each

E. PERITONEUM RIGHT SIDE WALL

Labeled with the patient's name, labeled "peritoneum right side wall", and received in formalin is a 9.0 x 3.0 x 0.3 cm portion of soft tan tissue.

About 90% of the peritoneal surface is coated by firm nodular and plaque-like aggregates of tumor.

Representative sections submitted.

Slide key:

- E1. Multiple

F. PERITONEUM LEFT SIDE WALL

Labeled with the patient's name, labeled "peritoneum left side wall", and received in formalin is a 9.0 x 6.0 x 0.5 cm portion of yellow-tan soft tissue.

About 90% of the peritoneum surface is coated by nodular and plaque-like aggregates of firm tan to tan-white tumor. The tumor deposits range from about 0.1 to 1.5 cm in diameter.

Representative sections are submitted.

Slide key:

- F1. 3

G. BLADDER PERITONEUM

Labeled with the patient's name, labeled "bladder peritoneum", and received in formalin is about a 9.5 x 3.5 x 0.5 cm portion of tan-yellow soft tissue.

About 75% of the specimen is coated by nodular and plaque-like aggregates of firm tan tumor. The tumor deposits range from about 0.1 to 1.5 cm in maximum dimension.

Representative sections are submitted.

Slide key:

- G1. 2

H. CECAL NODULE

[page 7 of 8]
Labeled with the patient's name, labeled "cecal nodule", and received in formalin is a 4.0 x 2.0 x 1.2 cm portion of tan-yellow fibroadipose tissue.

There are multiple tiny to small nodular and plaque-like aggregates of firm tan white tumor ranging from about 0.1 to 0.5 cm.

No large intestinal tissue is identified.

Representative sections are submitted.

Slide key:

H1. 3

I. HEPATIC FLEXURE NODULE

Labeled with the patient's name, labeled "hepatic flexure nodule", and received in formalin is a 6.0 x 3.0 x 1.7 cm portion of yellow-tan fibroadipose tissue.

The specimen is subtotally replaced by nodular aggregates of firm tan-white tumor. The tumor deposits involve at least 75% of the volume of the specimen.

Representative sections are submitted.

Slide key:

I1. 2

J. ILEOCECAL NODULE

Labeled with the patient's name, labeled "ileocecal nodule", and received in formalin is about a 0.7 x 0.4 x 0.3 cm fragment of firm tan-white tissue.

The tissue appears to consist mostly of tumor.

Entirely submitted.

Slide key:

J1. 1

K. OMENTAL NODULE

Labeled with the patient's name, labeled "omental nodule", and received in formalin is about a 3.5 x 1.5 x 1.5 cm partial omentectomy specimen.

The omentum is partially replaced by nodular and plaque-like aggregates of firm tan-white tumor. The tumor deposits range from about 0.1 to 1.5 cm in maximum dimension.

Representative sections are submitted.

Slide key:

K1. 2

L. INFUNDIBULAR PELVIC

Labeled with the patient's name, labeled "infundibular pelvic", and received in formalin is about a 2.0 x 1.2 x 0.3 cm portion of yellow-tan fibroadipose tissue.

There is a 0.5 cm diameter firm tan-white tumor nodule within the specimen.

[page 8 of 8]
[REDACTED]

Entirely submitted.

Slide key:

L1. 1

[REDACTED]

INTRAOPERATIVE CONSULTATION:
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN):

PART A OMENTUM [REDACTED]

- Metastatic adenocarcinoma, compatible with mullerian origin

[REDACTED]

[REDACTED]

[REDACTED]

This addendum is issued to report the findings in selected sections from Parts A, B, and C to be used for the TCGA studies. No additional studies are performed.

A. OMENTUM, PARTIAL OMENECTOMY (Block A2):

- Primary ovarian adenocarcinoma, with predominantly serous features, high grade
- Tumor cell nuclei ~ 80%
- Necrosis: 5%

B. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY (Block B1):

- Primary ovarian adenocarcinoma, with predominantly serous features, high grade
- Tumor cell nuclei ~ 85%
- Necrosis: 5%

C. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY (Block C1):

- Primary ovarian adenocarcinoma, with predominantly serous features, high grade
- Tumor cell nuclei ~ 70%
- Necrosis: 5%
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 1be7915b-c2a0-4f48-b0f7-fa56b14b9607 (TCGA-23-2643.8481BD3E-147D-4A67-ACDD-08FEA5BE431A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).